Somatic mutation profile of tumor specimen C3N-03460-02 (aliquot CPT0218760007) from CPTAC case C3N-03460, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 66.7 years (24,349 days).
Specimen C3N-03460-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73196d94-1fb6-4aa8-a5b9-886c2adddfc0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03460-71 (Blood Derived Normal), aliquot CPT0219120002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/479405ae-9e79-4bf2-8a3b-13dbb015be0d

The open-access MAF lists 40 somatic variants for this specimen: 19 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 19, Missense Mutation 18, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC008397.2 | c.1715G>A p.G572E | Missense Mutation (SNP) | VAF 26/829 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1480236852, COSV53207962; called by muse, mutect2
- AMER1 | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 32/923 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as rs1300950063, CD090026, COSV57665112; called by muse, mutect2
- CELSR1 | c.6735C>A p.N2245K | Missense Mutation (SNP) | VAF 23/537 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53091299; called by muse, mutect2
- FAM71A | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 20/612 reads (3%) | catalogued as COSV54236692; called by muse, mutect2
- MUC16 | c.29164G>A p.E9722K | Missense Mutation (SNP) | VAF 18/515 reads (3%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.031); catalogued as COSV67473438; called by muse, mutect2
- ZC3H12B | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 22/838 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.214); catalogued as COSV59051856; called by muse, mutect2
- ZNF275 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 16/518 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs782516737, COSV64703952; called by muse, mutect2
- CDC14A | c.895T>G p.F299V | Missense Mutation (SNP) | VAF 16/438 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2
- DIPK2B | c.352A>G p.S118G | Missense Mutation (SNP) | VAF 26/763 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2
- DUOXA1 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 34/653 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.081); called by muse, mutect2
- ERCC8 | c.238T>C p.S80P | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- MTMR3 | c.1803T>G p.D601E | Missense Mutation (SNP) | VAF 17/575 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- NFASC | c.1885G>A p.D629N (on ENST00000339876 / NM_001378329.1; = p.D625N on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/669 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.435); called by muse, mutect2
- PRRT4 | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 22/778 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); called by muse, mutect2
- SYNPO | c.2093C>T p.S698F (on ENST00000394243 / NM_001166208.2; = p.S454F on NM_007286.6) | Missense Mutation (SNP) | VAF 30/734 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TSSK3 | c.650A>G p.K217R | Missense Mutation (SNP) | VAF 23/765 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.158); called by muse, mutect2
- TTC34 | c.2039C>T p.S680F | Missense Mutation (SNP) | VAF 20/680 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZC3H7A | c.2569T>G p.F857V | Missense Mutation (SNP) | VAF 20/398 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.87); called by muse, mutect2
- ZNF316 | c.2812C>T p.R938C | Missense Mutation (SNP) | VAF 20/775 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); called by muse, mutect2
- ALDH1A2 | c.924C>T p.A308= | Silent (SNP) | VAF 16/428 reads (4%) | called by muse, mutect2
- CALCR | c.1062C>T p.Y354= (on ENST00000649521 / NM_001164737.2; = p.Y338= on NM_001742.4) | Silent (SNP) | VAF 21/563 reads (4%) | catalogued as COSV64013496; called by muse, mutect2
- CMKLR1 | c.96C>T p.S32= (on ENST00000312143 / NM_001142344.2; = p.S30= on NM_004072.3) | Silent (SNP) | VAF 17/476 reads (4%) | catalogued as COSV56439025; called by muse, mutect2
- DERL3 | c.552C>T p.F184= | Silent (SNP) | VAF 28/854 reads (3%) | called by muse, mutect2
- DUOXA2 | c.630G>A p.L210= | Silent (SNP) | VAF 20/637 reads (3%) | called by muse, mutect2
- HDAC6 | c.1101C>T p.T367= | Silent (SNP) | VAF 20/778 reads (3%) | called by muse, mutect2
- LRRC32 | c.1353G>A p.V451= | Silent (SNP) | VAF 24/740 reads (3%) | catalogued as rs1218944035; called by muse, mutect2
- MAGEC2 | c.1053A>G p.A351= | Silent (SNP) | VAF 28/648 reads (4%) | called by muse, mutect2
- OR52R1 | c.774C>T p.A258= | Silent (SNP) | VAF 15/548 reads (3%) | called by muse, mutect2
- OR9A2 | c.492C>T p.F164= | Silent (SNP) | VAF 12/338 reads (4%) | catalogued as COSV63306978; called by muse, mutect2
- PCDHA9 | c.1182C>T p.P394= | Silent (SNP) | VAF 23/669 reads (3%) | called by muse, mutect2
- PEG10 | c.360C>T p.F120= (on ENST00000482108 / NM_001040152.2; = p.F154= on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/654 reads (3%) | catalogued as COSV71788330; called by muse, mutect2
- R3HDM2 | c.951C>T p.D317= | Silent (SNP) | VAF 19/650 reads (3%) | called by muse, mutect2
- SCN10A | c.3909C>T p.F1303= | Silent (SNP) | VAF 24/562 reads (4%) | catalogued as rs928284057, COSV71860267; called by muse, mutect2
- SELE | c.1338C>T p.S446= | Silent (SNP) | VAF 25/507 reads (5%) | catalogued as COSV100324723; called by muse, mutect2
- SGCG | c.138C>T p.I46= | Silent (SNP) | VAF 16/315 reads (5%) | catalogued as rs1329079936; called by muse, mutect2
- SMCO4 | c.135C>T p.I45= | Silent (SNP) | VAF 18/646 reads (3%) | catalogued as rs972412916, COSV54360184; called by muse, mutect2
- ZNF624 | c.2532C>T p.A844= | Silent (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2, varscan2
- ZNF708 | c.753C>T p.L251= | Silent (SNP) | VAF 4/63 reads (6%) | called by muse, mutect2
- CDIPT | c.179-57G>A | Intron (SNP) | VAF 20/642 reads (3%) | called by muse, mutect2
- RPL28 | c.205+39T>C | Intron (SNP) | VAF 18/560 reads (3%) | called by muse, mutect2
